Somatic mutation profile of tumor specimen TCGA-76-6191-01A (aliquot TCGA-76-6191-01A-12D-1696-08) from TCGA case TCGA-76-6191, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.3 years (20,937 days).
Specimen TCGA-76-6191-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4e0b20e-8e06-4098-a815-25059787ef55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6191-10A (Blood Derived Normal), aliquot TCGA-76-6191-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6fafca8-a2ca-4e8e-9257-68bbda4232dc

The open-access MAF lists 60 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 14, Frame Shift Del 3, Nonsense Mutation 2, Intron 2, Frame Shift Ins 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCR6 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.771); catalogued as rs76452893; called by muse, mutect2, varscan2
- CHEK1 | c.499A>T p.M167L | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1393469843; called by muse, mutect2, varscan2
- COL6A1 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs1471278793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFR | c.1860C>G p.C620W | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51818096; called by muse, mutect2, varscan2
- EHHADH | c.1651C>T p.R551* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as rs138388673, COSV99213210; called by muse, mutect2, varscan2
- GRIN3A | c.3176G>A p.R1059Q | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs199945164, COSV62453970; called by muse, mutect2, varscan2
- H1-1 | c.513dup p.P172Tfs*11 | Frame Shift Ins (INS) | VAF 102/293 reads (35%) | catalogued as rs749012967; called by mutect2, varscan2
- KCNU1 | c.95T>C p.F32S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs1261558199; called by muse, mutect2, varscan2
- LDHAL6B | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV55686817; called by muse, mutect2, varscan2
- MS4A14 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1284059711; called by muse, mutect2, varscan2
- MS4A6E | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs761819409, COSV55726728, COSV55728023; called by muse, mutect2, varscan2
- NCOA5 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs150367556; called by muse, mutect2, varscan2
- NMUR2 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766887935; called by muse, mutect2, varscan2
- OR5D14 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs143761060, COSV100162533; called by muse, mutect2, varscan2
- OR5K1 | c.625T>A p.F209I | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV60304300; called by muse, mutect2, varscan2
- PLCZ1 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770563339, COSV56850134; called by muse, mutect2, varscan2
- PRAMEF20 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 156/424 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs924762274, COSV57080933; called by muse, mutect2, varscan2
- PRX | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.299); catalogued as rs377037656; called by muse, mutect2, varscan2
- PTEN | c.73T>G p.L25V | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs398123326, CD124225; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGS12 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs768591229; called by muse, mutect2, varscan2
- RYR1 | c.9082G>A p.G3028S | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.261); catalogued as rs548280516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SKAP2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1025140851, COSV61725796; called by muse, mutect2, varscan2
- SPOCK3 | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1289534072; called by muse, mutect2, varscan2
- ZFAND1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as rs1173671877, COSV55106673; called by muse, mutect2, varscan2
- AFM | c.1647G>C p.R549S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ANKRD46 | c.239_240del p.T80Sfs*22 | Frame Shift Del (DEL) | VAF 23/88 reads (26%) | called by pindel, varscan2
- CADM1 | c.209A>T p.D70V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CDH19 | c.938_940del p.E313del | In Frame Del (DEL) | VAF 14/35 reads (40%) | called by pindel, varscan2
- COL5A3 | c.1672C>A p.L558M | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL1 | c.2052del p.N685Mfs*4 | Frame Shift Del (DEL) | VAF 26/115 reads (23%) | called by mutect2, pindel, varscan2
- EEF1AKNMT | c.1903C>A p.P635T (on ENST00000361735 / NM_015935.5; = p.P549T on NM_014955.3) | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EP400 | c.3304+2T>C p.X1102_splice | Splice Site (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- KCNJ3 | c.1201T>A p.S401T | Missense Mutation (SNP) | VAF 92/207 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- KPRP | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP2 | c.12685G>T p.G4229C | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCF2L | c.1210G>T p.A404S (on ENST00000375608; = p.A372S on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MICU2 | c.1216A>C p.S406R | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- MS4A12 | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- OR6C75 | c.30del p.F10Lfs*6 | Frame Shift Del (DEL) | VAF 69/220 reads (31%) | called by pindel, varscan2
- PLCL2 | c.2689A>G p.R897G (on ENST00000615277 / NM_001144382.2; = p.R771G on NM_015184.5) | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- SOX7 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TCF20 | c.1795G>T p.V599F | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP42 | c.1515G>T p.W505C | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- VPS50 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- BRINP1 | c.627T>C p.N209= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV56296967; called by muse, mutect2, varscan2
- CD79B | c.213C>T p.S71= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs756340178, COSV50076332; called by muse, mutect2, varscan2
- DRC3 | c.1323C>T p.R441= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs1327734963; called by muse, mutect2, varscan2
- GJA5 | c.951T>C p.Y317= | Silent (SNP) | VAF 50/127 reads (39%) | called by muse, mutect2, varscan2
- GRIN2A | c.2763T>A p.A921= | Silent (SNP) | VAF 96/239 reads (40%) | called by muse, mutect2, varscan2
- LPA | c.4086C>A p.P1362= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV100307414; called by muse, mutect2
- MATN4 | c.1602C>T p.R534= (on ENST00000372754; = p.R493= on NM_003833.4) | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs757493559, COSV100636945; called by muse, mutect2, varscan2
- OR52R1 | c.99G>A p.P33= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs1189059558, COSV61887757, COSV61889205; called by muse, mutect2, varscan2
- OR5H1 | c.874C>T p.L292= | Silent (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- PPFIA1 | c.1383G>A p.R461= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs374923538; called by muse, mutect2, varscan2
- TGM5 | c.825C>T p.Y275= (on ENST00000220420 / NM_201631.4; = p.Y193= on NM_004245.4) | Silent (SNP) | VAF 32/53 reads (60%) | catalogued as rs138771869; called by muse, mutect2, varscan2
- THEG | c.984G>A p.K328= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as COSV61074979; called by muse, mutect2, varscan2
- TRAK1 | c.258G>A p.E86= | Silent (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- TRRAP | c.4854G>A p.G1618= (on ENST00000359863 / NM_001244580.1; = p.G1600= on NM_003496.3) | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV62855877; called by muse, mutect2, varscan2
- DOT1L | c.4606+1119G>T | Intron (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-2537G>A | Intron (SNP) | VAF 10/64 reads (16%) | catalogued as rs373274569; called by muse, mutect2, varscan2
